Somatic mutation profile of tumor specimen TCGA-D3-A8GI-06A (aliquot TCGA-D3-A8GI-06A-11D-A372-08) from TCGA case TCGA-D3-A8GI, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.2 years (26,722 days).
Specimen TCGA-D3-A8GI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5bd66ef-0ce7-420d-afd8-7549c80f81fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GI-10A (Blood Derived Normal), aliquot TCGA-D3-A8GI-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bd59802-3bb5-4f10-b5d7-50929079f891

The open-access MAF lists 6,246 somatic variants for this specimen: 4,017 protein-altering or splice-affecting, 2,066 silent, 163 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,689, Silent 2,066, Nonsense Mutation 212, Intron 69, Splice Region 54, RNA 53, Splice Site 43, 3'UTR 12, 5'UTR 11, 3'Flank 10, Frame Shift Del 9, 5'Flank 8.

Variants (750 of 6,246; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 76/128 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- CNGB3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as rs764742792, CM050554, COSV60684823; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL18A1 | c.2082dup p.V695Rfs*18 (on ENST00000359759 / NM_130444.3; = p.V460Rfs*18 on NM_030582.4) | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | catalogued as rs760175310; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYNC1H1 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs863223361, CM163684, COSV64138416; ClinVar: pathogenic; called by muse, varscan2
- GUCY2D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766646217, CM116134, COSV99644107; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199472730, CD044137, CM023402, CM057184, COSV99327610; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 45/74 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.4198C>T p.R1400* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as rs775112258, CM1311877, COSV70350217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LEP | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs104894023, CM981200, COSV58240705, COSV58240868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYF6 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.742); catalogued as rs747205109, COSV57353234; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 56/154 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.2980C>T p.R994W | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as rs757854282, COSV61870013; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs766209297, CM097906, COSV99298059; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 124/327 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMCO1 | c.616C>T p.R206* (on ENST00000612311 / NM_001256164.1; = p.R155* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs765379963, COSV100903179, COSV63319044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1298C>T p.P433L (on ENST00000373993 / NM_138932.2; = p.P425L on NM_014576.4) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99256938; called by muse, mutect2, varscan2
- A4GALT | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765662216, COSV99966687; called by muse, mutect2, varscan2
- A4GNT | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV99367934; called by muse, mutect2, varscan2
- AADAT | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100528671, COSV61787879; called by muse, mutect2, varscan2
- AASS | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV100741832, COSV62789987; called by muse, mutect2, varscan2
- AASS | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 160/300 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100741835; called by muse, mutect2, varscan2
- AASS | c.211-1G>A p.X71_splice | Splice Site (SNP) | VAF 114/226 reads (50%) | catalogued as COSV100741836; called by muse, mutect2, varscan2
- ABAT | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV99190988; called by muse, mutect2, varscan2
- ABCA12 | c.5981T>G p.L1994W (on ENST00000272895 / NM_173076.3; = p.L1676W on NM_015657.3) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790873; called by muse, mutect2, varscan2
- ABCA12 | c.4372G>A p.E1458K (on ENST00000272895 / NM_173076.3; = p.E1140K on NM_015657.3) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); catalogued as COSV99790877; called by muse, mutect2, varscan2
- ABCA12 | c.1733G>A p.R578K (on ENST00000272895 / NM_173076.3; = p.R260K on NM_015657.3) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs775306915, COSV55975019; called by muse, mutect2, varscan2
- ABCA7 | c.5233C>T p.L1745F | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as CD166825, COSV99566241; called by muse, mutect2, varscan2
- ABCA8 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 48/58 reads (83%) | catalogued as rs368751441; called by muse, mutect2, varscan2
- ABCA8 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99286204; called by muse, mutect2, varscan2
- ABCB1 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99713524; called by muse, mutect2, varscan2
- ABCB10 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100748009; called by muse, mutect2, varscan2
- ABCB11 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99792516; called by muse, mutect2, varscan2
- ABCB4 | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55939818; called by muse, mutect2, varscan2
- ABCB5 | c.3292C>T p.Q1098* (on ENST00000404938 / NM_001163941.2; = p.Q653* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 41/113 reads (36%) | catalogued as rs267601452, COSV51714293, COSV99328899; called by muse, mutect2, varscan2
- ABCC10 | c.2212C>T p.R738C (on ENST00000372530 / NM_001198934.2; = p.R710C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016532813, COSV99767187; called by muse, mutect2, varscan2
- ABCC11 | c.3540G>A p.G1180= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100750948; called by muse, mutect2, varscan2
- ABCC12 | c.3535T>G p.F1179V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100252925; called by muse, mutect2, varscan2
- ABCC12 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV100252927; called by muse, mutect2, varscan2
- ABCC5 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs758646463, COSV55586863; called by muse, mutect2, varscan2
- ABCC6 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52747455; called by muse, mutect2, varscan2
- ABCC6 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.243); catalogued as COSV99229132; called by mutect2, varscan2
- ABCC9 | c.2337G>A p.Q779= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99686282; called by muse, mutect2, varscan2
- ABCC9 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV53964272, COSV99686285; called by muse, mutect2, varscan2
- ABCE1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs755429648, COSV99668682; called by muse, mutect2, varscan2
- ABCF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770951242, COSV53051574; called by muse, mutect2, varscan2
- ABCG5 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53185872; called by muse, mutect2, varscan2
- ABCG8 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 168/352 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as rs746141470, COSV55393018; called by muse, varscan2
- ABCG8 | c.1231T>A p.F411I | Missense Mutation (SNP) | VAF 144/372 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV99700021; called by muse, varscan2
- ABHD16B | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998579488, COSV99410781; called by muse, mutect2, varscan2
- ABL1 | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs779131262, COSV100584283; called by muse, mutect2, varscan2
- ABLIM1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99522361; called by muse, varscan2
- ABLIM2 | c.360C>G p.D120E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV99589960; called by muse, mutect2
- ABO | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101505986; called by muse, mutect2, varscan2
- AC008676.3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV56637006; called by muse, mutect2, varscan2
- AC104389.6 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57963271; called by muse, mutect2, varscan2
- AC126283.2 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.077); catalogued as COSV101144547; called by muse, mutect2, varscan2
- AC244197.3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs782327392, COSV100558078; called by muse, mutect2, varscan2
- ACACA | c.4779C>T p.I1593= | Splice Region (SNP) | VAF 65/80 reads (81%) | catalogued as rs763027565; called by muse, mutect2, varscan2
- ACADL | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99284889; called by muse, mutect2, varscan2
- ACADL | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99284891; called by muse, mutect2, varscan2
- ACAN | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV104419288, COSV61366217; called by muse, mutect2, varscan2
- ACAN | c.4300T>G p.S1434A | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100718636; called by muse, varscan2
- ACAN | c.4622G>T p.G1541V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100718639; called by muse, mutect2, varscan2
- ACAN | c.5609G>A p.G1870E | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100718642; called by muse, mutect2, varscan2
- ACAN | c.6274G>A p.E2092K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as COSV100718646; called by muse, mutect2, varscan2
- ACAP3 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs868583747, COSV57641907; called by muse, mutect2, varscan2
- ACCS | c.1207T>C p.F403L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99772907; called by muse, mutect2, varscan2
- ACCSL | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV101122234; called by muse, mutect2, varscan2
- ACE2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 82/98 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV53023778; called by muse, mutect2, varscan2
- ACO2 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 324/510 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99347569; called by muse, mutect2, varscan2
- ACOT11 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV100650688; called by muse, mutect2, varscan2
- ACOXL | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61332518; called by muse, mutect2, varscan2
- ACP3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV60489485; called by muse, mutect2, varscan2
- ACSBG2 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV99397514; called by muse, mutect2, varscan2
- ACSBG2 | c.1517T>G p.L506R | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99397515; called by muse, mutect2, varscan2
- ACSL5 | c.1696C>A p.Q566K (on ENST00000354273; = p.Q622K on NM_016234.3) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100634688; called by muse, mutect2, varscan2
- ACSL6 | c.995C>T p.S332F (on ENST00000379240; = p.S357F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.652); catalogued as COSV99734180; called by muse, mutect2, varscan2
- ACSL6 | c.953C>T p.S318F (on ENST00000379240; = p.S343F on NM_001009185.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99734189; called by muse, mutect2, varscan2
- ACSM1 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54640805; called by muse, mutect2, varscan2
- ACSM1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54634883, COSV99533353; called by muse, mutect2, varscan2
- ACSM2A | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs565557207, COSV54589852; called by muse, mutect2, varscan2
- ACSM2A | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54584924; called by muse, mutect2
- ACSM2A | c.1421G>A p.G474E (on ENST00000219054; = p.G395E on NM_001308169.2) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525441; called by muse, mutect2, varscan2
- ACSM2B | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 120/404 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs562863484, COSV61658252; called by muse, mutect2, varscan2
- ACSM2B | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1199272295, COSV61657009, COSV61659260; called by muse, mutect2, varscan2
- ACSM2B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61660225; called by muse, mutect2, varscan2
- ACSM4 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV101257231, COSV68068556; called by muse, mutect2
- ACSM4 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748592689, COSV101257385, COSV68067084; called by muse, mutect2, varscan2
- ACSS3 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs185881304, COSV99699223; called by muse, mutect2, varscan2
- ACTN2 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100856884; called by muse, mutect2, varscan2
- ACTR1B | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100008146; called by muse, mutect2, varscan2
- ACVR1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55122376; called by muse, mutect2, varscan2
- ACY3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1305522687, COSV99663077; called by muse, mutect2, varscan2
- ADAM12 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs866308009, COSV100900842; called by muse, varscan2
- ADAM18 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55843937; called by muse, mutect2, varscan2
- ADAM18 | c.342C>T p.L114= | Splice Region (SNP) | VAF 38/80 reads (48%) | catalogued as COSV99695852, COSV99696068; called by muse, mutect2, varscan2
- ADAM18 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as rs767774627, COSV55843788, COSV55855271; called by muse, mutect2, varscan2
- ADAM18 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748944460, COSV55858283; called by muse, mutect2, varscan2
- ADAM18 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV99695388, COSV99695854; called by muse, mutect2, varscan2
- ADAM19 | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV99977748; called by muse, mutect2, varscan2
- ADAM2 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs542094562, COSV55858933; called by muse, mutect2, varscan2
- ADAM2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs866239502, COSV55860219; called by muse, mutect2, varscan2
- ADAM2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1384039342, COSV55859290; called by muse, mutect2, varscan2
- ADAM21 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs569652235, COSV99961199; called by muse, varscan2
- ADAM21 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99961204; called by muse, mutect2, varscan2
- ADAM28 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99737724; called by muse, mutect2, varscan2
- ADAM28 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV56098447, COSV56099005; called by muse, mutect2, varscan2
- ADAM29 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 168/234 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1173714434, COSV100821886, COSV100822111; called by muse, mutect2, varscan2
- ADAM29 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as rs865773772, COSV100822112; called by muse, mutect2, varscan2
- ADAM33 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.116); catalogued as rs763248965, COSV100597715, COSV62933883; called by muse, varscan2
- ADAM7 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as COSV99444365; called by muse, mutect2, varscan2
- ADAM7 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51534747; called by muse, mutect2, varscan2
- ADAM7 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51537003; called by muse, mutect2, varscan2
- ADAM7 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV51535057; called by muse, mutect2, varscan2
- ADAM7 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs777631956, COSV51535626; called by muse, mutect2, varscan2
- ADAMDEC1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV99836164; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV56476331; called by muse, mutect2, varscan2
- ADAMTS10 | c.606G>A p.W202* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV54356174; called by muse, mutect2, varscan2
- ADAMTS14 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774091612, COSV100941715; called by muse, mutect2, varscan2
- ADAMTS16 | c.2287C>T p.H763Y | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV99941278, COSV99941965; called by muse, mutect2, varscan2
- ADAMTS17 | c.2178G>A p.W726* | Nonsense Mutation (SNP) | VAF 105/220 reads (48%) | catalogued as COSV99171072; called by muse, mutect2, varscan2
- ADAMTS17 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as rs372097810; called by muse, mutect2
- ADAMTS18 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99273472; called by muse, mutect2, varscan2
- ADAMTS19 | c.1814A>T p.K605I | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV99179467; called by muse, mutect2, varscan2
- ADAMTS19 | c.3082G>A p.G1028R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV99179474; called by muse, mutect2, varscan2
- ADAMTS2 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs757688126, COSV99282978; called by muse, mutect2, varscan2
- ADAMTS20 | c.3941G>A p.G1314E | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101166342; called by muse, mutect2, varscan2
- ADAMTS3 | c.1485G>A p.A495= | Splice Region (SNP) | VAF 42/65 reads (65%) | catalogued as rs777412893, COSV99711515; called by muse, mutect2, varscan2
- ADAMTS6 | c.2791G>A p.G931R | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs562513614, COSV58685009; called by muse, mutect2, varscan2
- ADAMTS6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101125209, COSV66858879; called by muse, mutect2, varscan2
- ADAMTS6 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101125210; called by muse, mutect2, varscan2
- ADAMTS7 | c.3721C>G p.P1241A | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV101183163, COSV66305796; called by muse, mutect2, varscan2
- ADAMTS7 | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV101183165; called by muse, mutect2, varscan2
- ADAMTS9 | c.1711-1G>A p.X571_splice | Splice Site (SNP) | VAF 68/153 reads (44%) | catalogued as COSV99899818; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1345545620, COSV65887938; called by mutect2, varscan2
- ADAT1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 129/233 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs141697482; called by muse, mutect2, varscan2
- ADCY1 | c.2327+1G>A p.X776_splice | Splice Site (SNP) | VAF 38/130 reads (29%) | catalogued as COSV99812466; called by muse, mutect2, varscan2
- ADCY10 | c.3496C>T p.P1166S | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63243906; called by muse, mutect2, varscan2
- ADCY4 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100156685; called by muse, mutect2, varscan2
- ADCY4 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.714); catalogued as COSV100156194, COSV60253135; called by muse, mutect2, varscan2
- ADGRB3 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs148926519; called by muse, mutect2, varscan2
- ADGRB3 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV53257934; called by muse, varscan2
- ADGRB3 | c.3031C>T p.H1011Y | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99486029; called by muse, varscan2
- ADGRB3 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53238654; called by muse, mutect2, varscan2
- ADGRD1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV99896233; called by muse, mutect2, varscan2
- ADGRE1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 150/300 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0.038); catalogued as COSV99165476; called by muse, mutect2, varscan2
- ADGRF1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868151607, COSV51946345; called by muse, mutect2, varscan2
- ADGRF1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as rs750253635, COSV51948505; called by muse, mutect2, varscan2
- ADGRF1 | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs769330791, COSV99347434; called by muse, mutect2, varscan2
- ADGRF1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767876211, COSV51945369; called by muse, mutect2, varscan2
- ADGRF3 | c.1946G>A p.G649E (on ENST00000311519 / NM_001145168.1; = p.G450E on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100275201; called by muse, mutect2, varscan2
- ADGRG4 | c.3977G>A p.G1326E | Missense Mutation (SNP) | VAF 69/79 reads (87%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.461); catalogued as COSV54957612; called by muse, mutect2, varscan2
- ADGRG4 | c.6805G>A p.E2269K | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs1295700428, COSV54952143, COSV99794496; called by muse, mutect2, varscan2
- ADGRG4 | c.7567G>A p.E2523K | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs1239774960, COSV99796006; called by muse, mutect2, varscan2
- ADGRG4 | c.8449C>T p.H2817Y | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99796009; called by muse, mutect2, varscan2
- ADGRG4 | c.9041G>A p.G3014E | Missense Mutation (SNP) | VAF 68/83 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV99796012; called by muse, mutect2, varscan2
- ADGRG6 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as rs777589148, COSV51589053; called by muse, mutect2, varscan2
- ADGRL2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99590125; called by muse, mutect2, varscan2
- ADGRL2 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.426); catalogued as rs1471367918, COSV99590132; called by muse, mutect2, varscan2
- ADGRL3 | c.898G>A p.D300N (on ENST00000506720 / NM_001322402.2; = p.D232N on NM_015236.6) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs529635872, COSV101546856, COSV101547263; called by muse, mutect2, varscan2
- ADGRL3 | c.1283C>T p.S428L (on ENST00000506720 / NM_001322402.2; = p.S360L on NM_015236.6) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV101547105, COSV72265283; called by muse, mutect2, varscan2
- ADGRL4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs771201747, COSV66061203; called by muse, mutect2, varscan2
- ADGRV1 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101316175; called by muse, varscan2
- ADGRV1 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101316176; called by muse, mutect2, varscan2
- ADGRV1 | c.4325G>A p.G1442E | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101316177; called by muse, mutect2
- ADGRV1 | c.16502C>T p.S5501F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs866464814, COSV67980225; called by muse, mutect2, varscan2
- ADH1A | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV52925742, COSV99265858; called by muse, varscan2
- ADH1A | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99265860; called by muse, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2, varscan2
- ADH1B | c.570C>T p.V190= | Splice Region (SNP) | VAF 36/131 reads (27%) | catalogued as COSV100520812; called by muse, mutect2, varscan2
- ADH1B | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as rs1453332261, COSV100520813; called by muse, mutect2, varscan2
- ADH6 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99422575; called by muse, mutect2, varscan2
- ADH7 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99265343; called by muse, mutect2, varscan2
- ADSS2 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1490815303, COSV100836874; called by muse, mutect2, varscan2
- AFAP1 | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV100631812; called by muse, mutect2, varscan2
- AFM | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV99888973; called by muse, mutect2, varscan2
- AFM | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99888975; called by muse, mutect2, varscan2
- AFP | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56923673; called by muse, mutect2, varscan2
- AFP | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV56924389; called by muse, mutect2, varscan2
- AGBL1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs775454661, COSV101408147; called by muse, mutect2, varscan2
- AGL | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV99649611; called by muse, mutect2, varscan2
- AGR3 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV100124020; called by muse, mutect2, varscan2
- AHI1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1270940407, COSV55634067; called by muse, mutect2, varscan2
- AHNAK | c.5969C>T p.S1990F | Missense Mutation (SNP) | VAF 189/343 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99948364; called by muse, mutect2, varscan2
- AHNAK2 | c.12920C>T p.S4307L | Missense Mutation (SNP) | VAF 293/479 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368204450; called by muse, mutect2, varscan2
- AHNAK2 | c.10936C>T p.P3646S | Missense Mutation (SNP) | VAF 182/307 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1382525189, COSV100318214; called by muse, mutect2, varscan2
- AHNAK2 | c.8788G>A p.A2930T | Missense Mutation (SNP) | VAF 204/331 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs746928352, COSV60921907; called by muse, mutect2, varscan2
- AHNAK2 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs747036900, COSV60908719; called by muse, varscan2
- AIM2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV100931108; called by muse, mutect2, varscan2
- AK9 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1337455642, COSV100394007; called by muse, mutect2, varscan2
- AK9 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.561); catalogued as COSV99572628; called by muse, mutect2, varscan2
- AKAP13 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774102; called by muse, mutect2, varscan2
- AKAP3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962354; called by muse, mutect2, varscan2
- AKAP4 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 117/133 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100654315; called by muse, mutect2, varscan2
- AKAP4 | c.1422G>A p.M474I | Missense Mutation (SNP) | VAF 92/108 reads (85%) | SIFT tolerated (0.38); PolyPhen benign (0.176); catalogued as COSV62074241; called by muse, mutect2, varscan2
- AKAP6 | c.4639G>T p.E1547* | Nonsense Mutation (SNP) | VAF 78/137 reads (57%) | catalogued as COSV99802279; called by muse, mutect2, varscan2
- AKAP6 | c.5093C>T p.S1698F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55229491, COSV99802282; called by muse, mutect2, varscan2
- AKAP9 | c.2552C>T p.S851L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV100662652; called by muse, mutect2, varscan2
- AKR1C2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782570336, COSV101060374, COSV101060494; called by muse, mutect2, varscan2
- AKR7A3 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100853821; called by muse, mutect2, varscan2
- AKR7A3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs35216783, COSV100853822; called by muse, mutect2, varscan2
- AKT3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99795217, COSV99795915; called by muse, mutect2, varscan2
- AKT3 | c.393A>T p.E131D | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99795916; called by muse, mutect2, varscan2
- AL441992.2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1365483160, COSV100223314; called by muse, mutect2, varscan2
- AL592490.1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.172); catalogued as COSV101308236; called by muse, mutect2, varscan2
- AL592490.1 | c.499T>C p.S167P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs771750945, COSV101308237; called by muse, mutect2, varscan2
- ALB | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99891744; called by muse, mutect2, varscan2
- ALB | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.443); catalogued as rs868867553, COSV99891746; called by muse, mutect2, varscan2
- ALDH18A1 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1302919102, COSV100973234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH5A1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578023593, CM1511003, COSV100708833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDOB | c.434T>A p.F145Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878891; called by muse, mutect2, varscan2
- ALG10B | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1286064608, COSV100439938; called by muse, mutect2, varscan2
- ALLC | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV52998359, COSV99377356; called by muse, mutect2, varscan2
- ALMS1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100042993; called by muse, mutect2, varscan2
- ALPK2 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100864544; called by muse, mutect2, varscan2
- ALS2 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51883609, COSV51885889; called by muse, mutect2, varscan2
- AMBN | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 88/152 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534404; called by muse, mutect2, varscan2
- AMER2 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63436490; called by muse, mutect2, varscan2
- AMFR | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99316080; called by muse, mutect2, varscan2
- AMHR2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99143367; called by muse, mutect2, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, varscan2
- AMZ1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as rs1313847731, COSV100406503; called by muse, mutect2, varscan2
- ANGPT1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138754767, COSV52431155; called by muse, mutect2, varscan2
- ANGPT1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52435630; called by muse, mutect2, varscan2
- ANK1 | c.3097C>T p.L1033F | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55894091, COSV99225886; called by muse, mutect2, varscan2
- ANK1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99225888; called by muse, mutect2, varscan2
- ANK1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99225890; called by muse, mutect2, varscan2
- ANK2 | c.5467C>T p.P1823S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV100002686; called by muse, mutect2, varscan2
- ANK3 | c.4931C>T p.P1644L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1434764338, COSV99780925; called by muse, mutect2, varscan2
- ANK3 | c.4930C>T p.P1644S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99780926; called by muse, mutect2, varscan2
- ANK3 | c.3413C>T p.S1138F (on ENST00000280772 / NM_001320874.2; = p.S272F on NM_001149.3) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55053021; called by muse, varscan2
- ANKFN1 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 42/56 reads (75%) | catalogued as COSV59446429; called by muse, mutect2, varscan2
- ANKK1 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100392939; called by muse, mutect2, varscan2
- ANKK1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as rs267602697, COSV100392941; called by muse, varscan2
- ANKRD10 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV99941182; called by muse, mutect2, varscan2
- ANKRD24 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs754674717, COSV99517809; called by muse, mutect2, varscan2
- ANKRD26 | c.2633T>C p.I878T | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101063293; called by muse, mutect2, varscan2
- ANKRD30A | c.3586G>A p.E1196K (on ENST00000611781; = p.E1140K on NM_052997.2) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV64608794, COSV64613321; called by muse, mutect2, varscan2
- ANKRD30A | c.4162G>A p.E1388K (on ENST00000611781; = p.E1332K on NM_052997.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1332093611, COSV64607257; called by muse, mutect2, varscan2
- ANKRD35 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs369524282; called by muse, mutect2
- ANKRD35 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1553739222, COSV100841784, COSV62911158; called by muse, mutect2, varscan2
- ANKRD39 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV58413074; called by muse, mutect2, varscan2
- ANKRD46 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs267601678, COSV59513939, COSV59514594; called by muse, mutect2, varscan2
- ANKRD55 | c.1254A>C p.L418F | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV100591477; called by muse, mutect2, varscan2
- ANKS1B | c.2680G>A p.D894N (on ENST00000547776 / NM_152788.4; = p.D120N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs753813968, COSV100228346; called by muse, varscan2
- ANO2 | c.437C>T p.A146V (on ENST00000356134 / NM_001278597.3; = p.A150V on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV59034146; called by muse, mutect2
- ANO3 | c.411A>T p.E137D | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV99883909; called by muse, mutect2, varscan2
- ANO4 | c.1273G>A p.G425R (on ENST00000392977 / NM_001286615.2; = p.G390R on NM_178826.4) | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.905); catalogued as COSV100153219; called by muse, mutect2, varscan2
- ANO4 | c.2236C>T p.R746* (on ENST00000392977 / NM_001286615.2; = p.R711* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV54606613; called by muse, mutect2, varscan2
- ANO6 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100263533; called by muse, mutect2, varscan2
- ANO7 | c.328+1G>A p.X110_splice (on ENST00000274979; = p.X56_splice on NM_001001666.4) | Splice Site (SNP) | VAF 62/94 reads (66%) | catalogued as COSV99238902; called by muse, mutect2, varscan2
- ANO9 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765622452, COSV60383747; called by muse, mutect2, varscan2
- ANP32D | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 58/102 reads (57%) | catalogued as rs753531819, COSV99874352; called by muse, varscan2
- ANP32D | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV99874353; called by muse, varscan2
- ANPEP | c.2517G>A p.W839* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as COSV100263264; called by muse, mutect2, varscan2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, mutect2, varscan2
- ANTXR1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100362765; called by muse, mutect2
- ANXA13 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99146357; called by muse, mutect2, varscan2
- ANXA5 | c.292C>G p.H98D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV99634533; called by muse, mutect2, varscan2
- AOX1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65983750; called by muse, mutect2, varscan2
- AP2A1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100756370; called by muse, mutect2, varscan2
- AP2A2 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100173133; called by muse, mutect2, varscan2
- AP3D1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV100642821; called by muse, mutect2, varscan2
- AP3D1 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1277544941, COSV61427072; called by muse, mutect2, varscan2
- AP4E1 | c.2027C>G p.S676C | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99956850; called by muse, mutect2, varscan2
- APBA2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs199985120, COSV68792040; called by muse, mutect2, varscan2
- APBB1IP | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100774420; called by muse, mutect2, varscan2
- APBB1IP | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100882180; called by muse, mutect2, varscan2
- APBB1IP | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866267918, COSV66132627, COSV66134085; called by muse, mutect2, varscan2
- APOA2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99248347; called by muse, mutect2, varscan2
- APOB | c.13423G>A p.E4475K | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51942169; called by muse, mutect2, varscan2
- APOB | c.13306C>T p.L4436F | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV99266561; called by muse, mutect2, varscan2
- APOB | c.7312G>A p.E2438K | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV51948978; called by muse, mutect2, varscan2
- APOB | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266565; called by muse, mutect2, varscan2
- APOB | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047759477; called by muse, mutect2, varscan2
- APOB | c.696C>T p.T232= | Splice Region (SNP) | VAF 19/35 reads (54%) | catalogued as COSV51926821, COSV51935232; called by muse, mutect2, varscan2
- APOBEC1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs267603686, COSV57548632; called by muse, mutect2, varscan2
- APOBEC3B | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100213816; called by muse, varscan2
- APOBEC3F | c.723G>A p.Q241= | Splice Region (SNP) | VAF 30/217 reads (14%) | catalogued as COSV100415226; called by muse, mutect2
- APOBR | c.2926G>A p.E976K (on ENST00000431282; = p.E985K on NM_018690.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs1463817760, COSV100112701; called by muse, mutect2, varscan2
- APOL3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | PolyPhen benign (0); catalogued as COSV100652108; called by muse, mutect2, varscan2
- APOL3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | PolyPhen benign (0.005); catalogued as COSV100652111; called by muse, mutect2, varscan2
- APPBP2 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99319760; called by muse, mutect2, varscan2
- AQP7 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs558128835, COSV99953116; called by muse, mutect2, varscan2
- ARAP2 | c.3692C>T p.S1231F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs376590508; called by muse, mutect2, varscan2
- ARAP2 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752593167, COSV100394905; called by muse, mutect2, varscan2
- ARAP3 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99499990; called by muse, mutect2, varscan2
- ARFGEF2 | c.3797C>T p.S1266F | Missense Mutation (SNP) | VAF 107/359 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV64210242; called by muse, mutect2, varscan2
- ARFGEF3 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52459029; called by muse, mutect2, varscan2
- ARHGAP15 | c.297G>A p.R99= | Splice Region (SNP) | VAF 24/50 reads (48%) | catalogued as rs770470014; called by muse, mutect2
- ARHGAP15 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99712002; called by muse, mutect2, varscan2
- ARHGAP22 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs867270392, COSV50965914; called by muse, mutect2, varscan2
- ARHGAP24 | c.424C>T p.R142C (on ENST00000395184 / NM_001025616.3; = p.R49C on NM_031305.3) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs768287557, CM118080, COSV51986565; called by muse, mutect2, varscan2
- ARHGAP25 | c.1070C>T p.S357F (on ENST00000409202 / NM_001007231.3; = p.S349F on NM_014882.3) | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99771788; called by muse, mutect2, varscan2
- ARHGAP25 | c.1519C>T p.P507S (on ENST00000409202 / NM_001007231.3; = p.P499S on NM_014882.3) | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.374); catalogued as COSV99771791; called by muse, mutect2, varscan2
- ARHGAP26 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99191191; called by muse, mutect2, varscan2
- ARHGAP29 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53107636; called by muse, mutect2, varscan2
- ARHGAP29 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768915881, COSV99557872; called by muse, mutect2, varscan2
- ARHGAP30 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316917235, COSV100920356; called by muse, mutect2, varscan2
- ARHGEF15 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.321); catalogued as COSV100730081; called by muse, mutect2, varscan2
- ARHGEF17 | c.5095C>T p.P1699S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99736128; called by muse, mutect2, varscan2
- ARHGEF17 | c.5096C>T p.P1699L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55237971; called by muse, mutect2, varscan2
- ARHGEF28 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99709524; called by muse, mutect2, varscan2
- ARHGEF28 | c.4811G>A p.R1604K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as COSV99709528, COSV99710315; called by muse, mutect2, varscan2
- ARHGEF3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs775536031, COSV99575583; called by muse, mutect2, varscan2
- ARHGEF37 | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs773756400, COSV100381950; called by muse, mutect2, varscan2
- ARHGEF5 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753900000, COSV99282984; called by mutect2, varscan2
- ARHGEF6 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99166555; called by muse, mutect2, varscan2
- ARID3B | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100654676; called by muse, mutect2, varscan2
- ARMC12 | c.907G>A p.E303K (on ENST00000373866 / NM_001286574.2; = p.E330K on NM_145028.5) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99849511; called by muse, mutect2, varscan2
- ARMC4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99518793; called by muse, mutect2
- ARMC4 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1280670599, COSV99518797; called by muse, mutect2, varscan2
- ARMC9 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV100589860; called by muse, mutect2, varscan2
- ARMH3 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100898992; called by muse, mutect2, varscan2
- ARPC4 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99809565; called by muse, mutect2, varscan2
- ARPP21 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868857967, COSV51795120; called by muse, mutect2, varscan2
- ARSF | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV100839547; called by muse, mutect2, varscan2
- ASAH2 | c.1052del p.G351Efs*50 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as COSV61484364; called by mutect2, pindel*, varscan2
- ASAP2 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV55636904, COSV99856471; called by muse, mutect2, varscan2
- ASB5 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV56668979; called by muse, mutect2, varscan2
- ASCC3 | c.6035C>T p.S2012F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV100976727; called by muse, mutect2, varscan2
- ASH1L | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100853507; called by muse, mutect2, varscan2
- ASIC5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV73332897; called by muse, mutect2, varscan2
- ASL | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1170922579, COSV100508937; called by muse, mutect2, varscan2
- ASPDH | c.280C>A p.L94M (on ENST00000389208 / NM_001114598.2; = p.L39M on NM_001024656.3) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.855); catalogued as rs759824880, COSV100975982; called by muse, mutect2, varscan2
- ASTL | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100668398; called by muse, mutect2, varscan2
- ASTN1 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.969); catalogued as rs1353831135, COSV99922363; called by muse, mutect2, varscan2
- ASXL2 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV99711620; called by muse, mutect2, varscan2
- ATF4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.155); catalogued as rs1384839370, COSV57478511; called by muse, mutect2, varscan2
- ATG16L1 | c.1414C>T p.R472C (on ENST00000392017 / NM_030803.7; = p.R453C on NM_017974.4) | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61468059; called by muse, mutect2, varscan2
- ATP10B | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100469557; called by muse, mutect2, varscan2
- ATP10B | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1427500132, COSV100469562; called by muse, varscan2
- ATP13A3 | c.3761C>T p.T1254I (on ENST00000645319 / NM_001367549.1; = p.T1224I on NM_024524.3) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.152); catalogued as COSV99757361; called by muse, mutect2, varscan2
- ATP13A4 | c.3454C>T p.R1152W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376131238; called by muse, mutect2, varscan2
- ATP1A2 | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1314635188, COSV100767975; called by muse, mutect2, varscan2
- ATP1B2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV100006921; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- ATP2A1 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100707128; called by muse, mutect2, varscan2
- ATP6V0A4 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59477522; called by muse, mutect2, varscan2
- ATP8A2 | c.1768T>C p.Y590H | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99682101; called by muse, mutect2, varscan2
- ATP8B1 | c.3445A>C p.I1149L | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV99377512; called by muse, mutect2, varscan2
- ATP8B3 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.85); PolyPhen benign (0.033); catalogued as rs1159626933, COSV100034664; called by muse, mutect2, varscan2
- ATP9A | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV100125263; called by muse, mutect2, varscan2
- ATR | c.4633C>T p.Q1545* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as COSV100638367; called by muse, mutect2, varscan2
- ATRN | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.423); catalogued as COSV99497471; called by muse, varscan2
- ATRNL1 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1554971646, COSV58108888; called by muse, mutect2, varscan2
- ATXN2L | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100294745; called by muse, mutect2, varscan2
- ATXN7 | c.1072T>G p.C358G | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99894780; called by muse, mutect2, varscan2
- AWAT2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99339710; called by muse, mutect2, varscan2
- AXL | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs778883675, COSV56573369; called by muse, mutect2, varscan2
- B3GALNT1 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs756136988, COSV100252086; called by muse, mutect2, varscan2
- B3GALT1 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV59908009; called by muse, mutect2, varscan2
- B3GALT1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907874; called by muse, mutect2, varscan2
- B3GAT1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs368413334; called by muse, mutect2, varscan2
- B4GALNT1 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as COSV100247361, COSV57544855; called by muse, mutect2, varscan2
- B4GALNT4 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100327740; called by muse, mutect2, varscan2
- B4GALNT4 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100327742; called by muse, mutect2, varscan2
- BAAT | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 36/59 reads (61%) | catalogued as rs764187428, COSV52288701; called by muse, mutect2, varscan2
- BABAM2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1044374216, COSV100142243; called by muse, mutect2, varscan2
- BANK1 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.049); catalogued as COSV100536370, COSV100536570; called by muse, mutect2, varscan2
- BANP | c.1301C>T p.P434L (on ENST00000286122; = p.P406L on NM_079837.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV53744893; called by muse, mutect2, varscan2
- BASP1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100493792, COSV59474401; called by muse, mutect2, varscan2
- BBS9 | c.1913G>A p.G638E (on ENST00000242067 / NM_001348036.1; = p.G598E on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs776974656, COSV54168515; called by muse, mutect2, varscan2
- BCAM | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs762226358, COSV54305020; called by muse, varscan2
- BCAS1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.969); catalogued as COSV101006324; called by muse, mutect2, varscan2
- BCAS3 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1210943914, COSV101176371, COSV101176700; called by muse, mutect2, varscan2
- BCL11A | c.1513G>A p.E505K (on ENST00000335712 / NM_001365609.1; = p.E539K on NM_018014.4) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.059); catalogued as rs1248879509, COSV100186000; called by muse, mutect2, varscan2
- BCL11A | c.1190C>T p.S397L (on ENST00000335712 / NM_001365609.1; = p.S431L on NM_018014.4) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs138166869, COSV59625097; called by muse, mutect2, varscan2
- BCL3 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV99378232; called by muse, mutect2, varscan2
- BCL6B | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99546775; called by muse, mutect2, varscan2
- BCOR | c.3197C>T p.T1066I | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV100653562; called by muse, mutect2, varscan2
- BCR | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV100006727; called by muse, mutect2, varscan2
- BDKRB1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1464615714, COSV99387937; called by muse, mutect2, varscan2
- BDKRB1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145002930, COSV53706253; called by muse, mutect2, varscan2
- BEND5 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV100884141, COSV65716375; called by muse, mutect2, varscan2
- BEST2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs765991431, COSV99244527; called by muse, varscan2
- BEST3 | c.1352A>T p.K451M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100437853; called by muse, varscan2
- BEST3 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV100437856; called by muse, varscan2
- BEST3 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1486533635, COSV100437858; called by muse, mutect2, varscan2
- BEST3 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV100437860; called by muse, mutect2, varscan2
- BICRA | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as rs1263539422, COSV101194386; called by muse, mutect2, varscan2
- BLM | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759330541, COSV61922418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP3 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV51081556, COSV99261835; called by muse, mutect2, varscan2
- BMP6 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99307196; called by muse, mutect2, varscan2
- BMPER | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.383); catalogued as rs1228099396, COSV51814331; called by muse, mutect2
- BMPER | c.1947G>A p.W649* | Nonsense Mutation (SNP) | VAF 54/113 reads (48%) | catalogued as COSV99780019; called by muse, mutect2, varscan2
- BRCA2 | c.3260C>T p.T1087I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs1555283123, COSV101204458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRDT | c.1289T>C p.L430P | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100746506; called by muse, mutect2
- BRINP2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1221762863, COSV64176751; called by muse, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- BRINP3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs369089898; called by muse, mutect2, varscan2
- BRINP3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100819089, COSV66534354; called by muse, mutect2, varscan2
- BRPF1 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1559664290, COSV57404645; called by muse, mutect2, varscan2
- BRS3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 67/72 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV101036609; called by muse, mutect2, varscan2
- BSN | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV56528137; called by muse, mutect2, varscan2
- BSN | c.6215G>A p.R2072K | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.275); catalogued as COSV99609043; called by muse, mutect2, varscan2
- BSN | c.8114C>T p.S2705L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56514955; called by muse, mutect2, varscan2
- BTBD16 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99585039; called by muse, mutect2, varscan2
- BTG4 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.42); catalogued as COSV100604564; called by muse, mutect2, varscan2
- BTN3A2 | c.939G>A p.K313= | Splice Region (SNP) | VAF 39/165 reads (24%) | catalogued as COSV100709697; called by muse, mutect2, varscan2
- BTNL8 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1233522289, COSV51460687; called by muse, mutect2, varscan2
- BVES | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV100115020; called by muse, mutect2, varscan2
- C10orf71 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.264); catalogued as COSV60510773; called by muse, mutect2, varscan2
- C10orf71 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.11); catalogued as COSV100110383; called by muse, mutect2, varscan2
- C10orf71 | c.1769C>A p.T590N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100110386; called by muse, mutect2
- C11orf80 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.259); catalogued as rs1476749041, COSV100690969; called by muse, mutect2, varscan2
- C12orf40 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100210383; called by muse, mutect2, varscan2
- C12orf50 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.592); catalogued as COSV100072349; called by muse, varscan2
- C12orf50 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV100072350; called by muse, varscan2
- C14orf39 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV100407843; called by muse, mutect2, varscan2
- C15orf39 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV100641401; called by muse, mutect2, varscan2
- C16orf90 | c.350G>A p.G117E (on ENST00000399645 / NM_001353385.2; = p.G108E on NM_001080524.2) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV101290968; called by muse, mutect2, varscan2
- C16orf90 | c.349G>A p.G117R (on ENST00000399645 / NM_001353385.2; = p.G108R on NM_001080524.2) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV101290969; called by muse, mutect2, varscan2
- C18orf54 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as COSV100266611; called by muse, mutect2, varscan2
- C19orf44 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201618251, COSV55610301; called by muse, mutect2, varscan2
- C1QTNF2 | c.985G>A p.E329K (on ENST00000393975; = p.E284K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs768627769, COSV67433300; called by muse, mutect2, varscan2
- C1R | c.1421A>C p.Q474P (on ENST00000536053 / NM_001354346.2; = p.Q460P on NM_001733.7) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV101605630; called by muse, mutect2, varscan2
- C1orf112 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV99609967; called by muse, mutect2, varscan2
- C1orf141 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100924361; called by muse, mutect2, varscan2
- C1orf141 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV63992911; called by muse, mutect2, varscan2
- C1orf94 | c.716T>G p.L239R (on ENST00000488417 / NM_001134734.2; = p.L49R on NM_032884.5) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100975061; called by muse, mutect2, varscan2
- C1orf94 | c.1621C>T p.P541S (on ENST00000488417 / NM_001134734.2; = p.P351S on NM_032884.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64913054; called by muse, varscan2
- C1orf94 | c.1685G>A p.G562E (on ENST00000488417 / NM_001134734.2; = p.G372E on NM_032884.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975063; called by muse, varscan2
- C20orf85 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100959471; called by muse, mutect2, varscan2
- C22orf23 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs146578717; called by muse, mutect2, varscan2
- C22orf31 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV99326470; called by muse, mutect2, varscan2
- C2CD3 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV100487004; called by muse, mutect2, varscan2
- C2orf16 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV68843459; called by muse, mutect2, varscan2
- C2orf16 | c.4520G>A p.G1507E | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100820869, COSV62678960; called by muse, mutect2, varscan2
- C2orf16 | c.5256T>A p.S1752R | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.561); catalogued as COSV100820870, COSV100821012; called by muse, varscan2
- C2orf80 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100378504; called by muse, mutect2, varscan2
- C3 | c.3338A>G p.K1113R | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV99836907; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by muse, mutect2, varscan2
- C3orf20 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV99514269; called by muse, varscan2
- C3orf33 | c.197C>T p.S66L (on ENST00000340171 / NM_001308229.2; = p.S23L on NM_173657.2) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs773930331, COSV60898302; called by muse, mutect2, varscan2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- C3orf62 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs370943035; called by muse, mutect2, varscan2
- C3orf62 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99649480; called by muse, mutect2, varscan2
- C4B | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV101312159; called by muse, mutect2, varscan2
- C4orf51 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV101440006; called by muse, mutect2, varscan2
- C5AR1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as COSV100754040; called by muse, mutect2, varscan2
- C5AR2 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV99953821; called by muse, mutect2, varscan2
- C5orf46 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100568442; called by muse, mutect2, varscan2
- C6 | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99667403; called by muse, mutect2, varscan2
- C6orf118 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100024747; called by muse, mutect2, varscan2
- C6orf58 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.409); catalogued as rs746600754, COSV100314966; called by muse, mutect2, varscan2
- C7 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1263787334, COSV57474714; called by muse, mutect2, varscan2
- C7 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV100496162; called by muse, mutect2, varscan2
- C7orf26 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100732871, COSV100732950; called by muse, mutect2, varscan2
- C7orf33 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV100188852; called by muse, mutect2, varscan2
- C7orf61 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs535561832, COSV100190303; called by muse, mutect2, varscan2
- C8A | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100776573; called by muse, mutect2, varscan2
- C8A | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100776575; called by muse, mutect2, varscan2
- C8orf33 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100510567; called by muse, mutect2, varscan2
- C8orf76 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs747705071, COSV99415132; called by muse, varscan2
- C9 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99662267; called by muse, mutect2, varscan2
- C9orf72 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186531; called by muse, mutect2, varscan2
- CA1 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99810241; called by muse, mutect2, varscan2
- CA10 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563881; called by muse, mutect2, varscan2
- CA12 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV99458479; called by muse, mutect2, varscan2
- CA12 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51604806; called by muse, mutect2, varscan2
- CA3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV53409684; called by muse, mutect2, varscan2
- CA3 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.932); catalogued as COSV53411518; called by muse, varscan2
- CABP7 | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99334856; called by muse, mutect2, varscan2
- CABS1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV99909111; called by muse, mutect2, varscan2
- CACNA1A | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100802798; called by muse, mutect2, varscan2
- CACNA1E | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100703905; called by muse, mutect2, varscan2
- CACNA1G | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100662153; called by muse, mutect2, varscan2
- CACNA1I | c.5443G>A p.E1815K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100360846; called by muse, mutect2, varscan2
- CACNA1S | c.3667G>A p.D1223N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.078); catalogued as rs1235764442, COSV100755176; called by muse, mutect2, varscan2
- CACNA1S | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755177; called by muse, mutect2, varscan2
- CACNA1S | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV100755179, COSV62945101; called by muse, mutect2, varscan2
- CACNA2D1 | c.2590C>T p.H864Y (on ENST00000356253 / NM_001366867.1; = p.H852Y on NM_000722.4) | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100666915; called by muse, mutect2, varscan2
- CACNA2D1 | c.2195G>A p.R732Q (on ENST00000356253 / NM_001366867.1; = p.R720Q on NM_000722.4) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs79127167, COSV62372664; called by muse, mutect2, varscan2
- CACNA2D3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99875077, COSV99875197; called by muse, mutect2, varscan2
- CACNA2D3 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.791); catalogued as rs373496650, COSV55543373; called by muse, mutect2, varscan2
- CACNA2D4 | c.1878G>T p.G626= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99766011; called by muse, varscan2
- CADM3 | c.802G>A p.E268K (on ENST00000368125 / NM_001127173.3; = p.E302K on NM_021189.5) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0.038); catalogued as rs1218750519, COSV100930363; called by muse, mutect2, varscan2
- CAGE1 | c.1426G>A p.E476K (on ENST00000512086; = p.E340K on NM_205864.3) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866412142, COSV57074675; called by muse, mutect2, varscan2
- CALCR | c.1300G>A p.G434R (on ENST00000649521 / NM_001164737.2; = p.G418R on NM_001742.4) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1448985676, COSV100810396, COSV100810660; called by muse, mutect2, varscan2
- CALCR | c.1126C>T p.P376S (on ENST00000649521 / NM_001164737.2; = p.P360S on NM_001742.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100810665; called by muse, mutect2, varscan2
- CALCRL | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV101131005; called by muse, mutect2, varscan2
- CALHM5 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV62067757; called by muse, mutect2, varscan2
- CALML6 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV100205610; called by muse, mutect2, varscan2
- CAMK2A | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs544705728, COSV100804587; called by muse, mutect2, varscan2
- CAMSAP2 | c.2021C>T p.P674L (on ENST00000236925 / NM_001297707.2; = p.P663L on NM_203459.3) | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368251524, COSV99373715; called by muse, mutect2, varscan2
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by muse, mutect2, varscan2
- CAMTA1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100351400; called by muse, mutect2, varscan2
- CAPG | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775328091, COSV99809506; called by muse, mutect2, varscan2
- CAPN13 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99700500; called by muse, mutect2, varscan2
- CAPN13 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV99700501; called by muse, mutect2, varscan2
- CAPN15 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758164589; called by muse, mutect2, varscan2
- CAPRIN2 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as rs1353460657, COSV99195549; called by muse, mutect2
- CAPSL | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV101274292, COSV68439568; called by muse, mutect2, varscan2
- CAPZA3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868744411, COSV56849081, COSV56850605; called by muse, mutect2, varscan2
- CAPZA3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV56857223, COSV99856584; called by muse, mutect2, varscan2
- CARD10 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766748417, COSV99325168; called by muse, mutect2, varscan2
- CARD11 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV62717149; called by muse, mutect2, varscan2
- CARD14 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV60125635; called by muse, mutect2, varscan2
- CARD6 | c.1694G>T p.W565L | Missense Mutation (SNP) | VAF 114/200 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV99620989; called by muse, mutect2, varscan2
- CARMIL3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.431); catalogued as rs1458028939, COSV100549730; called by muse, mutect2, varscan2
- CARMIL3 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.506); catalogued as COSV100549732; called by muse, mutect2, varscan2
- CARS2 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99959791; called by muse, mutect2, varscan2
- CASQ1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.101); catalogued as rs570335623, COSV100927329; called by muse, mutect2, varscan2
- CASQ2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54768112; called by muse, mutect2, varscan2
- CASR | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV56136833; called by muse, mutect2, varscan2
- CASZ1 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV59741333; called by muse, mutect2, varscan2
- CATSPER1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as COSV100376095; called by muse, mutect2, varscan2
- CATSPER4 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1367050825, COSV58792581; called by muse, mutect2, varscan2
- CATSPERB | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99831478; called by muse, mutect2, varscan2
- CAVIN2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58424451; called by muse, mutect2, varscan2
- CBLN4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50352129, COSV50354495; called by muse, mutect2, varscan2
- CCDC110 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.769); catalogued as COSV100294059, COSV56869319; called by muse, mutect2, varscan2
- CCDC121 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV99270290; called by muse, mutect2, varscan2
- CCDC130 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99681292; called by muse, mutect2, varscan2
- CCDC136 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99922845; called by muse, mutect2, varscan2
- CCDC141 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55369047, COSV99837075; called by muse, mutect2, varscan2
- CCDC144A | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100138603; called by muse, mutect2, varscan2
- CCDC146 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as COSV99592815; called by muse, mutect2, varscan2
- CCDC146 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.153); catalogued as rs149903918; called by muse, mutect2, varscan2
- CCDC146 | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436875511, COSV99592818; called by muse, mutect2, varscan2
- CCDC148 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV51771872; called by muse, mutect2, varscan2
- CCDC158 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV101187289; called by muse, mutect2, varscan2
- CCDC172 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60938410; called by muse, mutect2, varscan2
- CCDC174 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514268; called by muse, mutect2, varscan2
- CCDC178 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100285556; called by muse, mutect2, varscan2
- CCDC178 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374081389, COSV100285557; called by muse, mutect2, varscan2
- CCDC18 | c.2707C>T p.Q903* (on ENST00000343253 / NM_001306076.1; = p.Q904* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as rs1009162190, COSV100159772; called by muse, mutect2
- CCDC181 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186158832, COSV100890351; called by muse, mutect2, varscan2
- CCDC183 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100566042; called by muse, mutect2, varscan2
- CCDC185 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1389901400, COSV64821548; called by muse, mutect2, varscan2
- CCDC186 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as COSV100991034; called by muse, mutect2, varscan2
- CCDC190 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100905834; called by muse, mutect2, varscan2
- CCDC191 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs778514406, COSV55670023; called by muse, mutect2, varscan2
- CCDC27 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99622729; called by muse, mutect2, varscan2
- CCDC38 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs201941109; called by muse, mutect2, varscan2
- CCDC39 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV56494787; called by muse, mutect2, varscan2
- CCDC50 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV101165328; called by muse, mutect2, varscan2
- CCDC54 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1317278207, COSV99660261; called by muse, mutect2, varscan2
- CCDC54 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV53758233, COSV99660262; called by muse, mutect2, varscan2
- CCDC54 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765197465, COSV99660263; called by muse, varscan2
- CCDC60 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59544614; called by muse, mutect2, varscan2
- CCDC60 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59551625; called by muse, mutect2, varscan2
- CCDC60 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199812180; called by muse, mutect2, varscan2
- CCDC68 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV61603145; called by muse, mutect2, varscan2
- CCDC69 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1232481878, COSV100815197; called by muse, mutect2, varscan2
- CCDC83 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as rs767776100, COSV99721817; called by muse, mutect2, varscan2
- CCDC83 | c.1198C>T p.P400S (on ENST00000342404 / NM_001286159.2; = p.P431S on NM_173556.5) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.91); catalogued as COSV99721820; called by muse, mutect2, varscan2
- CCIN | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV100631897; called by muse, mutect2, varscan2
- CCKAR | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.649); catalogued as COSV99810381; called by muse, mutect2, varscan2
- CCL24 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1554533485, COSV99768838; called by muse, mutect2, varscan2
- CCNA1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs746799158, COSV55221107; called by muse, mutect2, varscan2
- CCNB3 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1569542924, COSV99329362; called by muse, mutect2, varscan2
- CCNF | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV99563851; called by muse, mutect2, varscan2
- CCP110 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV101195303; called by muse, mutect2, varscan2
- CCR2 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99432536; called by muse, mutect2, varscan2
- CCRL2 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100645059; called by muse, mutect2, varscan2
- CCSER1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs964442979, COSV100393913; called by muse, mutect2, varscan2
- CCSER2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752738472, COSV56505544; called by muse, mutect2, varscan2
- CCT4 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV101075282; called by muse, mutect2, varscan2
- CD109 | c.4030C>T p.H1344Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV99754023; called by muse, mutect2, varscan2
- CD163 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100775982; called by muse, varscan2
- CD163 | c.779-1G>A p.X260_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100775984; called by muse, varscan2
- CD163L1 | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV100550336; called by muse, mutect2, varscan2
- CD163L1 | c.1644T>G p.N548K | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.974); catalogued as COSV100550337; called by muse, mutect2, varscan2
- CD177 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100946012; called by muse, mutect2
- CD1A | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 73/158 reads (46%) | catalogued as COSV99192506; called by muse, mutect2, varscan2
- CD1A | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as COSV99192510; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV101040463; called by muse, mutect2
- CD22 | c.1478G>A p.W493* | Nonsense Mutation (SNP) | VAF 46/88 reads (52%) | catalogued as COSV99323456; called by muse, mutect2, varscan2
- CD300A | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60409700; called by muse, mutect2, varscan2
- CD3E | c.86-1G>A p.X29_splice | Splice Site (SNP) | VAF 30/152 reads (20%) | catalogued as COSV100689016, COSV62345938; called by muse, mutect2, varscan2
- CD69 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1405030709, COSV99946137; called by muse, mutect2, varscan2
- CD79A | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99702053; called by muse, mutect2, varscan2
- CD86 | c.976G>A p.D326N (on ENST00000330540 / NM_175862.5; = p.D320N on NM_006889.4) | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1282173979, COSV52605021; called by muse, mutect2, varscan2
- CD93 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381174281, COSV99849355; called by muse, mutect2, varscan2
- CD96 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1035836810, COSV51917150; called by muse, mutect2, varscan2
- CDC16 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1254261915, COSV52960897; called by muse, mutect2, varscan2
- CDC20B | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99697155; called by muse, mutect2, varscan2
- CDC42BPA | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1220935233, COSV100506047; called by muse, mutect2, varscan2
- CDC42BPB | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489882007, COSV100775514; called by muse, mutect2, varscan2
- CDC7 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDCA2 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99648701; called by muse, mutect2, varscan2
- CDCA7 | c.425C>T p.S142L (on ENST00000347703 / NM_145810.3; = p.S221L on NM_031942.5) | Missense Mutation (SNP) | VAF 150/267 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372048796; called by muse, mutect2, varscan2
- CDCA7L | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1296475750, COSV100179781, COSV100181122; called by muse, mutect2, varscan2
- CDH10 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV52569365; called by muse, mutect2, varscan2
- CDH11 | c.2321A>G p.N774S | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99219088; called by muse, mutect2, varscan2
- CDH12 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV66389392; called by muse, mutect2, varscan2
- CDH12 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs967801376, COSV66426630; called by muse, mutect2, varscan2
- CDH13 | c.436T>A p.L146I | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV99227854; called by muse, mutect2, varscan2
- CDH20 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.713); catalogued as rs914343975, COSV53008421, COSV53010830; called by muse, mutect2, varscan2
- CDH22 | c.281A>C p.D94A | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100952930; called by muse, mutect2, varscan2
- CDH23 | c.9512G>A p.G3171E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1321844333, COSV56452343; called by muse, mutect2, varscan2
- CDH26 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54855743; called by muse, mutect2, varscan2
- CDH6 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54065315; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2, varscan2
- CDH7 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV59884758, COSV59897444; called by muse, mutect2, varscan2
- CDH8 | c.1416G>A p.R472= | Splice Region (SNP) | VAF 28/136 reads (21%) | catalogued as COSV54872649; called by muse, mutect2, varscan2
- CDH8 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54889201, COSV54903530; called by muse, mutect2, varscan2
- CDH9 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252882; called by muse, mutect2, varscan2
- CDH9 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50251740; called by muse, mutect2, varscan2
- CDH9 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV50374477, COSV99147166; called by muse, mutect2, varscan2
- CDHR2 | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs1398131203, COSV56138021; called by muse, mutect2, varscan2
- CDHR2 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs115224455, COSV99991861; called by muse, mutect2, varscan2
- CDK14 | c.825C>T p.F275= (on ENST00000380050 / NM_001287135.2; = p.F257= on NM_012395.3) | Splice Region (SNP) | VAF 62/108 reads (57%) | catalogued as rs202149959, COSV56026334; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5282C>T p.S1761F | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100575600; called by muse, mutect2, varscan2
- CDK9 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100953682; called by muse, mutect2, varscan2
- CDKN1A | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55190109; called by muse, mutect2, varscan2
- CDON | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs1555124296, COSV54998922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDX4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs758968054, COSV65171481; called by muse, mutect2, varscan2
- CEACAM1 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99362447; called by muse, mutect2, varscan2
- CEACAM16 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs755657951, COSV101312716; called by muse, mutect2, varscan2
- CEACAM20 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs1419792353, COSV100386953; called by muse, mutect2, varscan2
- CEACAM5 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.784); catalogued as COSV55750352; called by muse, mutect2, varscan2
- CECR2 | c.4438C>T p.P1480S (on ENST00000342247 / NM_001290047.2; = p.P1296S on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.048); catalogued as COSV52845849; called by muse, mutect2
- CELA3A | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV99266623; called by muse, mutect2, varscan2
- CELF3 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV51881563; called by muse, mutect2, varscan2
- CELF5 | c.1329C>T p.F443= | Splice Region (SNP) | VAF 46/61 reads (75%) | catalogued as rs769594842, COSV53014947; called by muse, varscan2
- CELSR1 | c.7634C>T p.T2545I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs745499744, COSV99418995; called by muse, varscan2
- CELSR1 | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs372128480; called by muse, mutect2, varscan2
- CEMIP | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54998476, COSV99586961; called by muse, mutect2, varscan2
- CEMIP2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); catalogued as COSV65488836; called by muse, mutect2, varscan2
- CENPE | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54386057; called by muse, mutect2, varscan2
- CEP128 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV53677335; called by muse, mutect2, varscan2
- CEP68 | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561079; called by muse, mutect2, varscan2
- CEPT1 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1277330069, COSV100718738; called by muse, mutect2, varscan2
- CER1 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.049); catalogued as rs1563781579, COSV101097891; called by muse, mutect2, varscan2
- CERKL | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs766773742, COSV100183883; called by muse, mutect2, varscan2
- CES1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239637259, COSV100828726, COSV62088023; called by muse, mutect2, varscan2
- CES5A | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99307743; called by muse, mutect2, varscan2
- CETN1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59121518; called by muse, mutect2, varscan2
- CETN1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs139897799, COSV100511432; called by muse, mutect2, varscan2
- CFAP221 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV54655992, COSV99732810; called by muse, mutect2, varscan2
- CFAP221 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV99732813; called by muse, mutect2, varscan2
- CFAP251 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as COSV56613362; called by muse, mutect2, varscan2
- CFAP299 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371270475, COSV63870358; called by muse, mutect2, varscan2
- CFAP300 | c.436-1G>A p.X146_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV101462472; called by muse, mutect2, varscan2
- CFAP43 | c.2686C>T p.L896F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99530861; called by muse, mutect2, varscan2
- CFAP46 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100886655; called by muse, mutect2, varscan2
- CFAP52 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1484109936, COSV100235377; called by muse, mutect2, varscan2
- CFAP53 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 75/99 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs919163455, COSV68352555; called by muse, mutect2, varscan2
- CFAP54 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV61573171; called by muse, mutect2, varscan2
- CFAP57 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs143690328; called by muse, mutect2, varscan2
- CFAP58 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100459015; called by muse, mutect2, varscan2
- CFAP61 | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV99845659; called by muse, mutect2, varscan2
- CFAP61 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.974); catalogued as rs746803306, COSV55630351, COSV99846170; called by muse, mutect2, varscan2
- CFAP65 | c.4720-1G>A p.X1574_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as COSV100445446; called by muse, mutect2, varscan2
- CFAP69 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV60187770; called by muse, mutect2, varscan2
- CFAP69 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100290300; called by muse, mutect2, varscan2
- CFAP91 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746475787, COSV99847277; called by muse, mutect2, varscan2
- CFH | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100809848; called by muse, mutect2, varscan2
- CFH | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs267598266, COSV100809850; called by muse, mutect2, varscan2
- CFH | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV100809851, COSV66407370; called by muse, mutect2, varscan2
- CFHR3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807553; called by muse, mutect2, varscan2
- CFHR3 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs754643554, COSV100807665; called by muse, mutect2, varscan2
- CFHR3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100807666; called by muse, mutect2, varscan2
- CFHR3 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100807668, COSV66402961; called by muse, mutect2, varscan2
- CFHR5 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV56828440; called by muse, mutect2
- CFL2 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 61/120 reads (51%) | catalogued as COSV99990549, COSV99990599; called by muse, mutect2, varscan2
- CFTR | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs397508381, CM980350, COSV50043996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFTR | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs193922508, COSV50046179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGNL1 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99848619; called by muse, mutect2
- CH25H | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs754613437, COSV64092264; called by mutect2, varscan2
- CHAF1A | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs764331314, COSV100011330; called by muse, mutect2, varscan2
- CHAT | c.1208G>A p.R403K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.95); catalogued as COSV100340451, COSV60330022; called by muse, mutect2, varscan2
- CHD1 | c.3971C>T p.S1324F | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV99399609; called by muse, mutect2, varscan2
- CHD4 | c.3581C>T p.T1194I (on ENST00000357008 / NM_001363606.2; = p.T1207I on NM_001273.5) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100538444; called by muse, mutect2, varscan2
- CHD5 | c.5003-1G>A p.X1668_splice | Splice Site (SNP) | VAF 64/139 reads (46%) | catalogued as COSV99314223; called by muse, mutect2, varscan2
- CHD5 | c.504C>T p.L168= | Splice Region (SNP) | VAF 34/76 reads (45%) | catalogued as COSV99314226; called by muse, mutect2, varscan2
- CHD6 | c.5725C>T p.Q1909* | Nonsense Mutation (SNP) | VAF 55/176 reads (31%) | catalogued as COSV100951191; called by muse, mutect2, varscan2
- CHD7 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.968); catalogued as COSV101418331; called by muse, mutect2, varscan2
- CHD8 | c.3900G>T p.K1300N (on ENST00000646647 / NM_001170629.2; = p.K1021N on NM_020920.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100783842; called by muse, mutect2
- CHD8 | c.3388C>T p.R1130C (on ENST00000646647 / NM_001170629.2; = p.R851C on NM_020920.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs376815460; called by muse, mutect2, varscan2
- CHKB | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376740; called by muse, mutect2, varscan2
- CHL1 | c.1704-1G>A p.X568_splice (on ENST00000397491 / NM_001253387.1; = p.X584_splice on NM_006614.4) | Splice Site (SNP) | VAF 42/111 reads (38%) | catalogued as rs1292215636, COSV99851636; called by muse, mutect2, varscan2
- CHL1 | c.3019G>A p.E1007K (on ENST00000397491 / NM_001253387.1; = p.E1023K on NM_006614.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV99851638; called by muse, mutect2, varscan2
- CHMP4A | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99841602; called by muse, mutect2, varscan2
- CHMP4C | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99794212; called by muse, mutect2, varscan2
- CHODL | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs776348043, COSV100166913; called by muse, mutect2, varscan2
- CHORDC1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1272968512, COSV100272103; called by muse, mutect2, varscan2
- CHPF2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1489909980, COSV99223214; called by muse, mutect2, varscan2
- CHRM1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV61006477; called by muse, mutect2, varscan2
- CHRM3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs201087854, COSV99698869; called by muse, varscan2
- CHRM3 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1208821081, COSV55090235, COSV55098641; called by muse, mutect2, varscan2
- CHRNA9 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59575428; called by muse, mutect2, varscan2
- CHRNA9 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | catalogued as COSV100039026; called by muse, varscan2
- CHRND | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV99285971; called by muse, mutect2, varscan2
- CHRND | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99285972; called by muse, mutect2, varscan2
- CHST1 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100346354; called by muse, mutect2, varscan2
- CHST8 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs762020676, COSV99381302; called by muse, mutect2, varscan2
- CHSY1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV99574053; called by muse, mutect2, varscan2
- CIB4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.129); catalogued as rs370372547, COSV99994975; called by muse, mutect2, varscan2
- CIITA | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as CM970948, COSV60863175; called by muse, mutect2, varscan2
- CILK1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100607849; called by muse, mutect2, varscan2
- CILP | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208182130, COSV99973640; called by muse, mutect2, varscan2
- CKM | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1430253523, COSV99488493; called by muse, mutect2, varscan2
- CKM | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.928); catalogued as COSV99488494; called by muse, mutect2, varscan2
- CKMT1A | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100787728; called by muse, mutect2, varscan2
- CKMT1B | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55853249; called by muse, mutect2, varscan2
- CLASP2 | c.1876A>C p.S626R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs1377483421, COSV100223812; called by muse, mutect2, varscan2
- CLCN5 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100260270; called by muse, mutect2, varscan2
- CLDN1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1357944333, COSV99790669; called by muse, mutect2, varscan2
- CLDN18 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764565705, COSV51735796; called by muse, mutect2, varscan2
- CLDN22 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032955; called by muse, mutect2, varscan2
- CLEC10A | c.676-1G>A p.X226_splice (on ENST00000254868 / NM_182906.4; = p.X202_splice on NM_006344.4) | Splice Site (SNP) | VAF 19/24 reads (79%) | catalogued as COSV54700814, COSV54702018, COSV99644595; called by muse, mutect2, varscan2
- CLEC18A | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs747133966, COSV99846993; called by muse, mutect2, varscan2
- CLEC18B | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); catalogued as rs201388061, COSV100376027; called by muse, mutect2, varscan2
- CLEC4D | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs868423919, COSV100223084, COSV55228953; called by muse, mutect2, varscan2
- CLEC4M | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99940692; called by muse, mutect2, varscan2
- CLEC6A | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV65986728; called by muse, varscan2
- CLGN | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100346717; called by muse, mutect2, varscan2
- CLIC5 | c.769C>T p.P257S (on ENST00000185206 / NM_001370649.1; = p.P98S on NM_016929.5) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51767315, COSV99484898; called by muse, mutect2, varscan2
- CLIP1 | c.2473C>T p.L825F (on ENST00000620786 / NM_001247997.1; = p.L814F on NM_002956.2) | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs575641700, COSV100212025; called by muse, mutect2, varscan2
- CLK1 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1406608028, COSV100362358; called by muse, mutect2, varscan2
- CLMP | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.313); catalogued as rs747365497, COSV101507415, COSV71649515; called by muse, mutect2, varscan2
- CLRN2 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99845892; called by muse, mutect2
- CLSTN2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV71717879; called by muse, mutect2, varscan2
- CLTC | c.1286A>T p.K429I | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99292573; called by muse, mutect2, varscan2
- CMKLR1 | c.563C>T p.S188F (on ENST00000312143 / NM_001142344.2; = p.S186F on NM_004072.3) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as COSV56441569; called by muse, mutect2, varscan2
- CMTM1 | c.452C>T p.S151F (on ENST00000457188 / NM_181269.3; = p.S268F on NM_052999.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV51748430; called by muse, mutect2, varscan2
- CMTR2 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100579230; called by muse, mutect2, varscan2
- CMYA5 | c.4780C>T p.P1594S | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1283706511, COSV101484175; called by muse, mutect2, varscan2
- CMYA5 | c.9857T>C p.F3286S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs750386523, COSV101484177; called by muse, mutect2, varscan2
- CNBD1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs771986009, COSV72917438; called by muse, mutect2, varscan2
- CNGA2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 87/100 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61705290; called by muse, mutect2, varscan2
- CNMD | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100937289, COSV100937336; called by muse, varscan2
- CNR2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100991513; called by muse, mutect2, varscan2
- CNTN1 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 75/135 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100751624; called by muse, mutect2, varscan2
- CNTN2 | c.795G>A p.G265= | Splice Region (SNP) | VAF 44/86 reads (51%) | catalogued as rs1328073418, COSV100085243; called by muse, mutect2, varscan2
- CNTN2 | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455112476, COSV100085247; called by muse, mutect2, varscan2
- CNTN4 | c.1609G>A p.G537R | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100639438; called by muse, mutect2, varscan2
- CNTN4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV61870303; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2
- CNTN5 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99678871; called by muse, mutect2, varscan2
- CNTN5 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54355238; called by muse, mutect2, varscan2
- CNTN6 | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 47/124 reads (38%) | catalogued as rs1048686229, COSV100611240; called by muse, mutect2, varscan2
- CNTNAP2 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668229, COSV100669300; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- CNTNAP2 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs372532510; called by muse, varscan2
- CNTNAP2 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV100668233, COSV62215270; called by muse, mutect2, varscan2
- CNTNAP2 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100668235; called by muse, mutect2, varscan2
- CNTNAP3 | c.2995+1G>A p.X999_splice | Splice Site (SNP) | VAF 9/17 reads (53%) | catalogued as rs1180838906, COSV99905160; called by muse, mutect2, varscan2
- CNTNAP3 | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV52671203; called by muse, varscan2
- CNTNAP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100272258; called by muse, mutect2, varscan2
- CNTNAP4 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs774408296, COSV56663445; called by muse, mutect2, varscan2
- CNTNAP4 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs375548298; called by muse, mutect2, varscan2
5,496 further variants in this file (3,267 protein-altering or splice-affecting, 2,066 silent, 163 other) are not listed here.
